Gene-level copy-number profile of tumor specimen TCGA-GV-A3JW-01A from TCGA case TCGA-GV-A3JW, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 74.2 years (27,091 days).
Specimen TCGA-GV-A3JW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.2f0b6bd5-10b5-41d1-a73e-52596b1fefed.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GV-A3JW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2fe26a73-06b4-4c8c-a1ad-fc248c50f5a8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 3,152; copy number 2: 20,694; copy number 3: 17,845; copy number 4: 15,350; copy number 5: 684; copy number 6: 825; copy number 7: 315; copy number 8: 194; copy number 9: 256; copy number 10: 122; copy number 11: 80; copy number 13: 46; copy number 14: 69; copy number 15: 21; copy number 16: 30; copy number 17: 16; copy number 18: 35; copy number 20: 33; copy number 22: 30; copy number 25: 1; copy number 26: 10; copy number 37: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GV-A3JW-01A-11D-A20B-01): tumor purity 0.84, ploidy 2.9, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,761 genes in 43 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:165,400,922–170,168,866, 122 genes, copy number 6–9 (broad region; genes not listed).
- chr1:170,211,010–170,211,457, 1 gene, copy number 6: ISCUP1.
- chr1:175,877,343–178,921,841, 42 genes, copy number 6 (within-gene range 3–6): LINC01657, LINC02803, RPS29P5, COP1, SCARNA3, AL590723.1, AL591043.2, U7, AL359265.2, RNU2-12P, AL359265.1, AL591043.1, MORF4L1P7, PAPPA2, PTP4A1P7, AL031290.1, ASTN1, MIR488, BRINP2, LINC01645, AL136114.1, LINC01741, SEC16B, CRYZL2P-SEC16B, CRYZL2P, AL359075.1, RASAL2-AS1, RASAL2, AL160281.1, AL365357.1, CLEC20A, Metazoa_SRP, AL513013.1, TEX35, C1orf220, RNA5SP69, AL137796.1, MIR4424, AL449106.1, RALGPS2, PTPN2P1, SNORA63.
- chr2:4,945,277–14,992,066, 154 genes, copy number 7–9 (broad region; genes not listed).
- chr3:6,770,001–7,741,533, 1 gene, copy number 8 (within-gene range 2–8): GRM7.
- chr3:7,241,916–14,178,621, 144 genes, copy number 5–10 (within-gene range 3–10) (broad region; genes not listed).
- chr3:14,402,576–17,205,165, 63 genes, copy number 6–8 (within-gene range 3–8) (broad region; genes not listed).
- chr4:56,049,073–75,101,943, 286 genes, copy number 5–8 (broad region; genes not listed).
- chr4:81,919,995–82,013,095, 3 genes, copy number 5: COX5BP1, AC021863.1, NPM1P41.
- chr5:5,688,805–10,440,388, 104 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr5:42,423,439–42,721,878, 1 gene, copy number 5 (within-gene range 2–5): GHR.
- chr5:42,729,138–44,389,706, 44 genes, copy number 5: AC113368.1, CCDC152, SELENOP, AC008945.1, AC008945.2, PPIAP77, PRELID3BP4, PRELID3BP5, PRELID3BP6, PRELID3BP7, AC008875.3, AC008875.2, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3, NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1, RNU6-381P, FGF10.
- chr5:53,480,626–53,819,722, 3 genes, copy number 6 (within-gene range 2–6): FST, NDUFS4, LINC02105.
- chr5:75,831,255–77,166,909, 34 genes, copy number 5: AC108120.3, AC108120.2, BIN2P2, AC108120.1, SAP18P1, AC026774.2, AC026774.1, SV2C, RNA5SP186, AC113404.2, AC113404.3, HMGN2P4, PDCD5P2, AC113404.1, SNRPCP2, IQGAP2, AC112173.1, AC026725.1, F2RL2, AC025188.1, AC025188.2, AC025188.3, F2R, F2RL1, RN7SL208P, S100Z, RNU6ATAC36P, CRHBP, AGGF1, AC008581.2, ZBED3, AC008581.1, SNORA47, ZBED3-AS1.
- chr5:115,691,462–117,546,298, 30 genes, copy number 6–9 (within-gene range 1–9): AC008549.2, AC008549.1, H3P24, RNU2-49P, CDO1, ATG12, AP3S1, LINCADL, LVRN, DDX43P1, ARL14EPL, AC034236.1, AC034236.3, AC034236.2, COMMD10, RNU6-644P, HMGN2P27, AC018752.1, SEMA6A, SEMA6A-AS1, RPS14P8, SEMA6A-AS2, RPS17P2, LINC02214, AC010267.1, AC093534.1, AC093534.2, RPL35AP15, AC093295.1, LINC00992.
- chr5:163,039,291–166,382,599, 27 genes, copy number 6: MRPL57P6, AC008723.1, CCNG1, NUDCD2, HMMR, HMMR-AS1, MAT2B, AC010291.1, AC116917.1, RNU6-168P, AC008432.1, LSM1P2, AC008662.1, AC008662.2, AC109466.1, LINC02143, AC008446.1, RNU6-209P, AC091973.1, LINC01938, AC008415.1, RN7SKP60, AC008562.1, AC008489.1, RPL7P20, AC114321.1, AC026403.1.
- chr7:13,854,355–29,013,367, 251 genes, copy number 7–26 (broad region; genes not listed).
- chr7:29,806,486–38,932,394, 182 genes, copy number 5–10 (broad region; genes not listed).
- chr7:51,716,657–62,275,678, 179 genes, copy number 9–14 (broad region; genes not listed).
- chr8:31,639,222–33,045,445, 12 genes, copy number 18 (within-gene range 2–18): NRG1, AC068931.1, NRG1-IT1, RNA5SP262, RNA5SP263, NRG1-IT3, AC083977.1, RNU6-663P, AC090204.1, MTND1P6, MTND2P32, RANP9.
- chr9:10,532,145–17,797,124, 79 genes, copy number 6–7 (broad region; genes not listed).
- chr9:137,306,896–138,203,325, 24 genes, copy number 5 (within-gene range 4–5): EXD3, NOXA1, ENTPD8, NSMF, MIR7114, PNPLA7, MRPL41, DPH7, ZMYND19, ARRDC1, AL590627.2, ARRDC1-AS1, EHMT1, Metazoa_SRP, SETP5, AL590627.1, MIR602, AL772363.1, CACNA1B, AL591424.1, IL9RP1, TUBBP5, AL591424.2, AL954642.1.
- chr10:8,619,933–10,462,361, 18 genes, copy number 5: CHCHD3P1, RNA5SP299, AL355333.1, LINC02676, AC044784.1, LINC00709, AL138773.1, HSP90AB7P, LINC02663, LINC02670, ELOCP3, Y_RNA, CUX2P1, AL354916.1, AL583859.1, CELF2-DT, AL583859.2, AL583859.3.
- chr11:80,653,429–85,627,922, 49 genes, copy number 5–6 (within-gene range 2–6): ARL6IP1P3, LINC02720, AP003398.1, AP003398.2, AP003464.1, MTND4LP18, MTND6P25, MIR4300HG, AP002802.2, MIR4300, AP002802.1, AP000793.1, RPS28P7, FAM181B, LINC02734, RBMXP3, PRCP, EIF2S2P6, DDIAS, AP000893.1, AP000893.2, RAB30, AP001767.1, SNORA70E, RAB30-DT, AP001767.2, AP001767.3, COX5BP4, C1DP5, BCAS2P1, PCF11, AP000873.4, AP000873.2, PCF11-AS1, ANKRD42, CKS1BP4, AP000873.3, AP000873.1, CCDC90B, AP000446.1, CYCSP28, AP000446.2, DLG2, DLG2-AS2, AP002370.1, LDHAL6DP, HNRNPA1P72, AP000852.1, AP001825.1.
- chr12:3,367,833–4,276,252, 16 genes, copy number 15: LINC02417, PRMT8, AC005908.2, AC005908.1, THCAT155, CRACR2A, AC005831.1, RNU6-174P, AC006207.1, PARP11, OTUD4P1, PARP11-AS1, AC084375.1, HSPA8P5, AC007207.1, CCND2-AS1.
- chr12:45,014,672–46,876,784, 32 genes, copy number 5–6: DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, AC009248.3, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4.
- chr12:71,938,845–75,432,688, 35 genes, copy number 5 (within-gene range 4–5): TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35, CHCHD3P2, AC133480.1, AC090503.2, LINC02444, AC090503.1, AC087879.1, RNU6-1012P, LINC02445, U8, LINC02882, AC136188.1, LINC02394, AC090502.3, AC090502.2, AC090502.1, VENTXP3, ATXN7L3B, AC025257.1, AC123904.2, AC123904.1, AC123904.3, AC073525.1, KCNC2, CAPS2-AS1, CCNG2P1, CAPS2, AC092552.1, AC121761.2, GLIPR1L1, GLIPR1L2.
- chr13:28,820,348–38,066,444, 136 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).
- chr15:52,056,675–53,129,698, 23 genes, copy number 18: AC023906.5, AC023906.2, AC023906.1, BCL2L10, GNB5, AC023906.3, AC023906.4, Y_RNA, CERNA1, MYO5C, MIR1266, MYO5A, EEF1B2P1, ARPP19, AC025917.1, FAM214A, AC009754.1, AC009754.2, ONECUT1, AC016044.1, RPSAP55, EEF1A1P22, LINC02490.
- chr15:85,380,571–85,794,925, 16 genes, copy number 13: AKAP13, MIR7706, RNU7-79P, FABP5P9, AC087286.3, AC087286.2, AC087286.1, RNU6-1280P, AC087286.4, AC021739.3, AC021739.2, AC021739.4, LINC02883, KLHL25, MIR1276, AC021739.1.
- chr16:7,726,841–8,112,756, 2 genes, copy number 7: AC005774.1, AC093515.1.
- chr16:23,835,983–30,113,537, 207 genes, copy number 5–22 (within-gene range 2–22) (broad region; genes not listed).
- chr16:46,469,341–49,275,579, 70 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr18:51,612,639–51,613,110, 1 gene, copy number 25: RSL24D1P9.
- chr18:56,597,209–57,072,119, 7 genes, copy number 22–37 (within-gene range 2–37): TXNL1, WDR7, AC012301.1, U3, WDR7-OT1, AC012301.2, LINC-ROR.
- chr18:58,416,765–58,834,364, 21 genes, copy number 14: AC105105.2, MIR122HG, MIR122, MIR3591, AC105105.4, ALPK2, AC105105.3, AC105105.1, AC104971.2, SNORA108, RPL9P31, AC104971.3, AC104971.1, MALT1, AC104365.1, MRPL37P1, AC104365.3, AC104365.2, RNU6-219P, LINC01926, U8.
- chr19:7,750,684–9,019,984, 60 genes, copy number 6: RPL21P129, CLEC4M, CLEC4GP1, EXOSC3P2, EVI5L, PRR36, AC010336.3, LYPLA2P2, 5S_rRNA, LRRC8E, AC010336.1, MAP2K7, AC010336.4, TGFBR3L, AC010336.2, SNAPC2, CTXN1, AC010336.5, TIMM44, AC010336.7, ELAVL1, AC010336.6, AC008946.1, CCL25, FBN3, AC022146.1, CERS4, AC022146.2, CD320, AC010323.1, NDUFA7, RPS28, KANK3, AC010323.2, ANGPTL4, RAB11B-AS1, MIR4999, RAB11B, MARCHF2, AC136469.1, AC136469.2, HNRNPM, PRAM1, ZNF414, MYO1F, AC092316.1, ADAMTS10, AC130469.1, NFILZ, AC243312.1, ACTL9, OR2Z1, RPL23AP78, AC012616.1, ZNF558, AC008734.1, MBD3L1, AC008734.2, MUC16, BOLA3P2.
- chr19:19,211,958–21,064,261, 92 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr19:27,638,483–32,829,580, 101 genes, copy number 6–11 (within-gene range 4–11) (broad region; genes not listed).
- chr20:17,187,510–21,115,197, 86 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,497. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
